Gene-level copy-number profile of tumor specimen TCGA-DK-A2I1-01A from TCGA case TCGA-DK-A2I1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.2 years (26,726 days).
Specimen TCGA-DK-A2I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.822fdeac-85dd-47dd-a991-49f6b5dbe188.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A2I1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e43e3535-a7c6-4418-b68f-4a9a3669afce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 324; copy number 2: 17,491; copy number 3: 20,429; copy number 4: 15,397; copy number 5: 2,088; copy number 6: 3,463; copy number 7: 276; copy number 8: 70; copy number 9: 24; copy number 10: 163; copy number 12: 26; copy number 15: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A2I1-01A-11D-A17S-01): tumor purity 0.58, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.
- chr9:21,695,176–22,455,740, 18 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 588 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,800,511–163,923,873, 153 genes, copy number 10–15 (broad region; genes not listed).
- chr1:171,314,183–173,064,015, 36 genes, copy number 7–10 (within-gene range 2–10): FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1.
- chr1:211,936,249–212,414,901, 16 genes, copy number 8 (within-gene range 4–8): AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1.
- chr3:12,484,432–12,539,623, 3 genes, copy number 10 (within-gene range 5–10): TSEN2, RNA5SP123, RNU6-377P.
- chr3:103,524,033–117,139,389, 183 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:161,600,438–165,846,519, 18 genes, copy number 7–10 (within-gene range 6–10): AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322.
- chr3:187,197,090–189,897,276, 31 genes, copy number 7–10: AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 10: MTAPP2.
- chr6:6,144,084–6,622,771, 7 genes, copy number 12 (within-gene range 5–12): F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1.
- chr6:38,715,311–40,715,363, 32 genes, copy number 8 (within-gene range 5–8): DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1.
- chr7:17,205,652–17,680,659, 6 genes, copy number 7: Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr10:6,682,513–7,118,469, 8 genes, copy number 7 (within-gene range 4–7): AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3, LINC02665.
- chr10:7,818,505–8,016,631, 1 gene, copy number 12 (within-gene range 5–12): TAF3.
- chr10:8,045,378–11,764,070, 42 genes, copy number 9–12: GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3.
- chr10:18,140,424–21,293,011, 32 genes, copy number 7–8 (within-gene range 4–8): CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1, MALRD1, UBE2V2P1, AL590378.1, HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675, NEBL, MTND1P21, AL157398.1, EIF4BP2, NPM1P30.
- chr10:23,694,746–24,547,848, 4 genes, copy number 7 (within-gene range 5–7): KIAA1217, NUP35P1, AC063961.1, MIR603.
- chr16:47,724,568–48,448,402, 15 genes, copy number 8–10: LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3.

Autosomal genes at a single copy (total copy number 1): 323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
